Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A7U9, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A7U9-06A (Metastatic).

DERMATOPATHOLOGY
Case Number :

TCO-0-3
Melanoma NOS 872013
Site: Inguinal lymph node
C77.4
9/5/14

Diagnosis:

- A. Lymph nodes, left inguinal, dissection
-Metastatic melanoma involving 12 out of 13 lymph nodes (some of which are matted or completely replaced lymph nodes), with the largest diameter measuring 6 cm (12/13)
-Extracapsular extension is extensive
Updated AJCC Staging: pT3b pN3 pMx
- B. Left femoral canal lymph node, removal
-No evidence of melanoma in 2 lymph nodes (0/2)

Clinical History:

year old female, left groin lymph node dissection; melanoma

Gross Description:

- A: The specimen was received labeled with the patient's name and measured 13 x 11 x 3 cm. There is a group of matted tan lymph nodes that appears to have tumor which measures 6 x 4 x 3 cm. Fresh tumor is taken by tissue procurement. The fibrofatty specimen is serially sectioned and then placed in . Lymph node candidates are identified and submitted as A1-10. Tissue remains in formalin.
- B: The specimen was received labeled with the patient's name and measured 25 x 17 x 4 mm. The tissue is entirely submitted as blocks B1-2.

Source: NCI Genomic Data Commons file 1349f2e6-8df9-46db-8176-f5bd338638c4 (TCGA-FR-A7U9.CEAE4ACD-340C-4BB2-A606-98445E57FED7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).